Somatic mutation profile of tumor specimen ALCH-B466-TTP1-A (aliquot ALCH-B466-TTP1-A-1-0-D-A80E-36) from ALCHEMIST case ALCH-B466, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 60.3 years (22,013 days).
Specimen ALCH-B466-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d10b6735-36c5-48c1-93f2-cdc5a3973353.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B466-NB1-A (Blood Derived Normal), aliquot ALCH-B466-NB1-A-1-0-D-A80E-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0f3902a1-eda0-42cc-8b46-03a21a9ce475

The open-access MAF lists 129 somatic variants for this specimen: 97 protein-altering or splice-affecting, 20 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 79, Silent 20, Nonsense Mutation 13, Intron 6, Splice Site 3, 3'UTR 3, 5'UTR 2, Splice Region 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 99/781 reads (13%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.733G>C p.G245R | Missense Mutation (SNP) | VAF 38/722 reads (5%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / uncertain significance / likely pathogenic; called by muse, mutect2
- ADAM30 | c.257G>T p.R86L | Missense Mutation (SNP) | VAF 20/299 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV65561334; called by muse, mutect2
- ATP8B3 | c.1984G>A p.A662T | Missense Mutation (SNP) | VAF 26/392 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769225269, COSV59541288; called by muse, mutect2
- COL9A2 | c.1831C>T p.R611W | Missense Mutation (SNP) | VAF 36/580 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs531953673, COSV65623802; called by muse, mutect2
- CTR9 | c.1126G>A p.E376K | Missense Mutation (SNP) | VAF 12/242 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs869312709, COSV63727939; ClinVar: uncertain significance; called by muse, mutect2
- CYP2C19 | c.436C>T p.Q146* | Nonsense Mutation (SNP) | VAF 32/853 reads (4%) | catalogued as COSV64906629; called by muse, mutect2
- EPPIN-WFDC6 | c.454A>T p.R152* | Nonsense Mutation (SNP) | VAF 46/832 reads (6%) | catalogued as rs1223892673; called by muse, mutect2
- F9 | c.829G>C p.V277L | Missense Mutation (SNP) | VAF 33/834 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as CM057676; called by muse, mutect2
- FAM47A | c.988C>A p.P330T | Missense Mutation (SNP) | VAF 24/440 reads (5%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV60495697; called by muse, mutect2
- GRIA1 | c.1597G>C p.D533H | Missense Mutation (SNP) | VAF 22/651 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.245); catalogued as COSV99603254; called by muse, mutect2
- GSR | c.1537A>G p.T513A | Missense Mutation (SNP) | VAF 59/1038 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs896909854; called by muse, mutect2
- KPRP | c.821G>T p.R274L | Missense Mutation (SNP) | VAF 16/344 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.208); catalogued as COSV64222590; called by muse, mutect2
- LANCL3 | c.633G>T p.Q211H | Missense Mutation (SNP) | VAF 20/348 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs1184413053; called by muse, mutect2
- LRSAM1 | c.410A>G p.N137S | Missense Mutation (SNP) | VAF 18/296 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1178102555; called by muse, mutect2
- MED13L | c.245A>T p.E82V | Missense Mutation (SNP) | VAF 74/935 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56122879; called by muse, mutect2
- MTA3 | c.1142G>T p.S381I | Missense Mutation (SNP) | VAF 30/350 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101290714; called by muse, mutect2
- NDUFAF4 | c.124G>C p.E42Q | Missense Mutation (SNP) | VAF 46/794 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.091); catalogued as rs760369602; called by muse, mutect2
- OR8I2 | c.433G>T p.G145* | Nonsense Mutation (SNP) | VAF 26/372 reads (7%) | catalogued as COSV56167102; called by muse, mutect2
- PCDHB16 | c.2158G>T p.A720S | Missense Mutation (SNP) | VAF 23/662 reads (3%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.014); catalogued as COSV53368977; called by muse, mutect2
- PPP1R21 | c.770G>T p.G257V | Missense Mutation (SNP) | VAF 12/254 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as COSV99681707; called by muse, mutect2
- RAP2C | c.422C>A p.P141H | Missense Mutation (SNP) | VAF 50/1104 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV61683349; called by muse, mutect2
- RIMS2 | c.4351G>T p.G1451* (on ENST00000666250 / NM_001348490.2; = p.G1022* on NM_014677.5 and 7 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 35/650 reads (5%) | catalogued as COSV51665046; called by muse, mutect2
- RPP30 | c.247G>T p.D83Y | Missense Mutation (SNP) | VAF 17/290 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53295855, COSV53297664; called by muse, mutect2
- SLC8A1 | c.1169C>A p.A390D | Missense Mutation (SNP) | VAF 11/274 reads (4%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.956); catalogued as COSV60473539; called by muse, mutect2
- SPARCL1 | c.1840G>A p.A614T | Missense Mutation (SNP) | VAF 28/350 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56803719; called by muse, mutect2
- TFAP2B | c.602-1G>T p.X201_splice | Splice Site (SNP) | VAF 60/1086 reads (6%) | catalogued as rs1275985863; called by muse, mutect2
- TNR | c.3403C>A p.P1135T | Missense Mutation (SNP) | VAF 24/432 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54921225; called by muse, mutect2
- TRMT44 | c.1666G>T p.G556C | Missense Mutation (SNP) | VAF 40/534 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.827); catalogued as rs372502016; called by muse, mutect2
- TSHZ3 | c.1447G>T p.E483* | Nonsense Mutation (SNP) | VAF 84/1372 reads (6%) | catalogued as COSV53668504; called by muse, mutect2
- ZEB2 | c.2586G>T p.L862F | Missense Mutation (SNP) | VAF 21/271 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99066028; called by muse, mutect2
- ZNF831 | c.3965C>G p.P1322R | Missense Mutation (SNP) | VAF 52/588 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as COSV64037089; called by muse, mutect2
- AMER3 | c.2392G>T p.A798S | Missense Mutation (SNP) | VAF 17/358 reads (5%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.47); called by muse, mutect2
- ANGPT4 | c.92G>T p.R31M | Missense Mutation (SNP) | VAF 24/414 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.137); called by muse, mutect2
- APAF1 | c.553G>T p.V185F (on ENST00000551964 / NM_181861.2; = p.V174F on NM_001160.3) | Missense Mutation (SNP) | VAF 34/464 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); called by muse, mutect2
- ATP1A2 | c.2440-2A>T p.X814_splice | Splice Site (SNP) | VAF 32/755 reads (4%) | called by muse, mutect2
- BEND2 | c.1605C>A p.D535E | Missense Mutation (SNP) | VAF 30/548 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); called by muse, mutect2
- BTBD7 | c.2699C>T p.S900L | Missense Mutation (SNP) | VAF 40/670 reads (6%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.01); called by muse, mutect2
- CEP164 | c.4345C>T p.L1449F | Missense Mutation (SNP) | VAF 19/300 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CHRNA4 | c.384-4C>G | Splice Region (SNP) | VAF 58/668 reads (9%) | called by muse, mutect2
- CLDN34 | c.128C>A p.S43* | Nonsense Mutation (SNP) | VAF 23/419 reads (5%) | called by muse, mutect2
- DCDC1 | c.4199C>T p.S1400F (on ENST00000597505 / NM_001367979.1; = p.S507F on NM_020869.3) | Missense Mutation (SNP) | VAF 26/740 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.043); called by muse, mutect2
- DNAH8 | c.11418G>A p.M3806I | Missense Mutation (SNP) | VAF 44/750 reads (6%) | SIFT tolerated (0.37); PolyPhen benign (0.085); called by muse, mutect2
- DOCK1 | c.1547G>T p.R516M | Missense Mutation (SNP) | VAF 56/958 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- DOCK1 | c.1548G>T p.R516S | Missense Mutation (SNP) | VAF 56/958 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- EHBP1 | c.1766G>T p.S589I | Missense Mutation (SNP) | VAF 14/166 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.333); called by muse, mutect2
- ELAPOR2 | c.2969A>T p.E990V (on ENST00000450689 / NM_001142749.3; = p.E823V on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/476 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.848); called by muse, mutect2
- ERC2 | c.1075-4C>T | Splice Region (SNP) | VAF 32/392 reads (8%) | called by muse, mutect2
- F13A1 | c.1194C>A p.S398R | Missense Mutation (SNP) | VAF 56/855 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2
- FGF23 | c.656T>A p.M219K | Missense Mutation (SNP) | VAF 14/278 reads (5%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.001); called by muse, mutect2
- FKTN | c.1131G>T p.M377I | Missense Mutation (SNP) | VAF 48/744 reads (6%) | SIFT tolerated (0.35); PolyPhen benign (0.001); called by muse, mutect2
- FRMPD3 | c.752G>T p.R251L | Missense Mutation (SNP) | VAF 16/261 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2
- FUT6 | c.698T>A p.M233K | Missense Mutation (SNP) | VAF 30/874 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.474); called by muse, mutect2
- GPKOW | c.241C>T p.Q81* | Nonsense Mutation (SNP) | VAF 24/514 reads (5%) | called by muse, mutect2
- GRIA3 | c.751-1G>A p.X251_splice | Splice Site (SNP) | VAF 17/325 reads (5%) | called by muse, mutect2
- HAX1 | c.227A>G p.H76R | Missense Mutation (SNP) | VAF 46/972 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.241); called by muse, mutect2
- HELZ2 | c.245C>T p.P82L | Missense Mutation (SNP) | VAF 16/147 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HK3 | c.2488C>T p.Q830* | Nonsense Mutation (SNP) | VAF 14/381 reads (4%) | called by muse, mutect2
- HOXB2 | c.862G>T p.G288W | Missense Mutation (SNP) | VAF 17/143 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- KCNC2 | c.1055T>G p.F352C | Missense Mutation (SNP) | VAF 31/388 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- KIF26B | c.5639C>A p.P1880Q | Missense Mutation (SNP) | VAF 15/248 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- KLHL32 | c.585G>T p.K195N | Missense Mutation (SNP) | VAF 32/519 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.86); called by muse, mutect2
- LAMB2 | c.3131G>T p.G1044V | Missense Mutation (SNP) | VAF 36/764 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MARS2 | c.127G>T p.V43L | Missense Mutation (SNP) | VAF 30/482 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2
- MSN | c.1411C>A p.H471N | Missense Mutation (SNP) | VAF 38/690 reads (6%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.494); called by muse, mutect2
- NCKAP1L | c.2278G>A p.A760T | Missense Mutation (SNP) | VAF 56/978 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2
- NEUROD1 | c.968C>A p.A323D | Missense Mutation (SNP) | VAF 35/436 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.136); called by muse, mutect2
- NF1 | c.7342G>T p.E2448* (on ENST00000358273 / NM_001042492.3; = p.E2427* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 46/800 reads (6%) | called by muse, mutect2
- NKX2-6 | c.404C>A p.P135Q | Missense Mutation (SNP) | VAF 21/239 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- OLFM3 | c.1343C>T p.A448V (on ENST00000338858 / NM_001288821.1; = p.A428V on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/320 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.247); called by muse, mutect2
- OPHN1 | c.864T>A p.Y288* | Nonsense Mutation (SNP) | VAF 25/692 reads (4%) | called by muse, mutect2
- OR2AJ1 | c.811G>A p.D271N | Missense Mutation (SNP) | VAF 24/310 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.1); called by muse, mutect2
- OR52W1 | c.70G>A p.G24R | Missense Mutation (SNP) | VAF 22/290 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); called by muse, mutect2
- OTOG | c.4295G>T p.C1432F | Missense Mutation (SNP) | VAF 16/230 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PEX5L | c.700G>T p.E234* | Nonsense Mutation (SNP) | VAF 59/569 reads (10%) | called by muse, mutect2, varscan2
- PLEKHF2 | c.599C>T p.P200L | Missense Mutation (SNP) | VAF 56/866 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); called by muse, mutect2
- PLPPR4 | c.1964G>A p.G655D | Missense Mutation (SNP) | VAF 16/264 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.157); called by muse, mutect2
- POGK | c.358G>T p.E120* | Nonsense Mutation (SNP) | VAF 12/141 reads (9%) | called by muse, mutect2
- PPP4R1 | c.2281G>T p.E761* (on ENST00000400556 / NM_001042388.3; = p.E744* on NM_005134.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 41/648 reads (6%) | called by muse, mutect2
- RABL3 | c.149A>T p.Y50F | Missense Mutation (SNP) | VAF 25/294 reads (9%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.987); called by muse, mutect2
- RBMXL3 | c.1708G>T p.D570Y | Missense Mutation (SNP) | VAF 21/269 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.959); called by muse, mutect2
- RNF187 | c.440G>T p.R147L | Missense Mutation (SNP) | VAF 36/568 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.186); called by muse, mutect2
- SH3BP4 | c.2171G>T p.R724M | Missense Mutation (SNP) | VAF 10/202 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.299); called by muse, mutect2
- SHROOM2 | c.1804C>A p.P602T | Missense Mutation (SNP) | VAF 17/312 reads (5%) | SIFT tolerated (0.43); PolyPhen benign (0.071); called by muse, mutect2
- SIGLEC9 | c.214G>T p.A72S | Missense Mutation (SNP) | VAF 18/471 reads (4%) | SIFT tolerated (0.27); PolyPhen benign (0.062); called by muse, mutect2
- SLC16A2 | c.789C>A p.F263L | Missense Mutation (SNP) | VAF 39/1149 reads (3%) | SIFT tolerated (0.89); PolyPhen benign (0.023); called by muse, mutect2
- SLC35G1 | c.835C>T p.P279S (on ENST00000427197 / NM_001134658.3; = p.P278S on NM_153226.4) | Missense Mutation (SNP) | VAF 14/198 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TG | c.1189G>T p.A397S | Missense Mutation (SNP) | VAF 42/890 reads (5%) | SIFT tolerated (0.46); PolyPhen benign (0.01); called by muse, mutect2
- TLN2 | c.6836G>A p.G2279D | Missense Mutation (SNP) | VAF 28/498 reads (6%) | SIFT tolerated (0.42); PolyPhen benign (0.078); called by muse, mutect2
- TMEM222 | c.422G>C p.C141S | Missense Mutation (SNP) | VAF 29/297 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- TPO | c.2642C>A p.T881K | Missense Mutation (SNP) | VAF 104/1194 reads (9%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.025); called by muse, mutect2
- USP17L10 | c.813C>A p.N271K | Missense Mutation (SNP) | VAF 39/66 reads (59%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, varscan2
- XK | c.190C>A p.R64S | Missense Mutation (SNP) | VAF 36/807 reads (4%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.9); called by muse, mutect2
- ZBTB34 | c.818G>T p.G273V | Missense Mutation (SNP) | VAF 38/476 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZHX1-C8orf76 | c.868G>T p.G290W | Missense Mutation (SNP) | VAF 32/515 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); called by muse, mutect2
- ZNF280A | c.909C>G p.C303W | Missense Mutation (SNP) | VAF 27/367 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF512B | c.1906G>T p.G636C | Missense Mutation (SNP) | VAF 17/178 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABCC5 | c.2007T>A p.I669= | Silent (SNP) | VAF 28/442 reads (6%) | called by muse, mutect2
- ALG10B | c.414A>T p.A138= | Silent (SNP) | VAF 41/765 reads (5%) | called by muse, mutect2
- ARPC2 | c.45C>T p.L15= | Silent (SNP) | VAF 14/320 reads (4%) | called by muse, mutect2
- COL6A5 | c.5574G>T p.T1858= (on ENST00000312481; = p.T1854= on NM_153264.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 52/886 reads (6%) | called by muse, mutect2
- CTNND2 | c.267T>A p.T89= | Silent (SNP) | VAF 17/498 reads (3%) | called by muse, mutect2
- DSE | c.1254G>A p.K418= | Silent (SNP) | VAF 22/272 reads (8%) | called by muse, mutect2
- FRMPD3 | c.753G>T p.R251= | Silent (SNP) | VAF 16/268 reads (6%) | catalogued as COSV99346050; called by muse, mutect2
- HTR5A | c.636G>T p.P212= | Silent (SNP) | VAF 36/720 reads (5%) | catalogued as COSV55287343, COSV99839482; called by muse, mutect2
- ITIH5 | c.1887C>A p.R629= | Silent (SNP) | VAF 14/334 reads (4%) | called by muse, mutect2
- KCNC1 | c.969G>A p.K323= | Silent (SNP) | VAF 16/324 reads (5%) | called by muse, mutect2
- KHSRP | c.1065G>T p.R355= | Silent (SNP) | VAF 11/280 reads (4%) | called by muse, mutect2
- KRT35 | c.612C>A p.R204= | Silent (SNP) | VAF 34/442 reads (8%) | called by muse, mutect2
- KRTAP9-1 | c.390G>A p.R130= | Silent (SNP) | VAF 46/547 reads (8%) | called by muse, mutect2
- PPP6R1 | c.2445C>T p.P815= | Silent (SNP) | VAF 20/404 reads (5%) | called by muse, mutect2
- RECQL4 | c.702C>T p.S234= | Silent (SNP) | VAF 24/448 reads (5%) | catalogued as rs907039783; ClinVar: likely benign; called by muse, mutect2
- TAPBP | c.252G>T p.R84= | Silent (SNP) | VAF 5/63 reads (8%) | catalogued as rs1386765002; called by muse, mutect2
- TRPM6 | c.861G>T p.P287= | Silent (SNP) | VAF 44/922 reads (5%) | catalogued as COSV100665384; called by muse, mutect2
- VHLL | c.300C>G p.L100= | Silent (SNP) | VAF 32/682 reads (5%) | called by muse, mutect2
- WFDC3 | c.501C>T p.G167= | Silent (SNP) | VAF 20/153 reads (13%) | called by muse, mutect2
- ZFYVE26 | c.627G>T p.S209= | Silent (SNP) | VAF 23/254 reads (9%) | catalogued as COSV100720495; called by muse, mutect2
- BZW2 | c.*16C>A | 3'UTR (SNP) | VAF 22/436 reads (5%) | called by muse, mutect2
- IL2RG | c.-2C>A | 5'UTR (SNP) | VAF 25/520 reads (5%) | called by muse, mutect2
- LRRC75B | c.177+489G>C | Intron (SNP) | VAF 36/581 reads (6%) | called by muse, mutect2
- NDUFAF5 | c.*379C>T | 3'UTR (SNP) | VAF 26/636 reads (4%) | called by muse, mutect2
- NPIPB1P | n.967C>T | RNA (SNP) | VAF 58/1066 reads (5%) | catalogued as rs1433793369; called by muse, mutect2
- NRP1 | c.1864+52G>T | Intron (SNP) | VAF 30/516 reads (6%) | called by muse, mutect2
- P3H1 | c.-49C>A | 5'UTR (SNP) | VAF 16/262 reads (6%) | called by muse, mutect2
- SEMA4G | c.*665C>T | 3'UTR (SNP) | VAF 11/132 reads (8%) | called by muse, mutect2
- SLC13A1 | c.99+9272G>T | Intron (SNP) | VAF 16/438 reads (4%) | called by muse, mutect2
- ZBBX | c.2138-5976G>T | Intron (SNP) | VAF 23/326 reads (7%) | called by muse, mutect2
- ZEB2 | c.73+5051C>A | Intron (SNP) | VAF 12/294 reads (4%) | called by muse, mutect2
- ZIC4 | c.-16+887G>T | Intron (SNP) | VAF 30/1036 reads (3%) | called by muse, mutect2
